Surgical pathology report (de-identified scan), TCGA case TCGA-CR-7368, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma), tissue source site Vanderbilt University, specimen TCGA-CR-7368-01A (Primary Tumor).

[page 1 of 5]
SURGICAL PATHOLOGY REPORT

Accession number: [REDACTED]

Final Report

DIAGNOSIS:

- 1) ORAL MUCOSA, FLOOR OF MOUTH, RIGHT, BIOPSY: INFILTRATING MODERATELY DIFFERENTIATED KERATINIZING SQUAMOUS CELL CARCINOMA.
- 2) LYMPH NODE, LEVEL 1, ADJACENT TO FACIAL ARTERY, EXCISION: 1 LYMPH NODE, NEGATIVE FOR MALIGNANCY.
- 3) SOFT TISSUE, LINGUAL NERVE, DISTAL RIGHT, BIOPSY: SALIVARY GLAND TISSUE, NEGATIVE FOR MALIGNANCY.
- 4) SOFT TISSUE, RIGHT TONGUE, DEEP, BIOPSY: SALIVARY GLAND AND SKELETAL MUSCLE, NEGATIVE FOR MALIGNANCY.
- 5) MANDIBULAR MARGIN, RIGHT POSTERIOR MEDIAL, EXCISION: SALIVARY GLAND, NEGATIVE FOR MALIGNANCY.
- 6) ALVEOLAR MARGIN, RIGHT POSTERIOR, EXCISION: SQUAMOUS MUCOSA, SUBMUCOSA, AND SKELETAL MUSCLE, NEGATIVE FOR MALIGNANCY.
- 7) LYMPH NODES, LEVEL 2 AND 3, NECK, RIGHT, EXCISION: 2 LYMPH NODES, NEGATIVE FOR MALIGNANCY.
- 8) LYMPH NODES, LEVEL 4, NECK, RIGHT, EXCISION: 5 LYMPH NODES, NEGATIVE FOR MALIGNANCY.
- 9) LYMPH NODES, LEVEL 2B, NECK, RIGHT, EXCISION: 5 LYMPH NODES, NEGATIVE FOR MALIGNANCY.
- 10) LYMPH NODES, LEVELS 2 AND 3, NECK, ANTERIOR RIGHT, EXCISION: 19 LYMPH NODES, NEGATIVE FOR MALIGNANCY.
- 11) LYMPH NODES, LEVEL 1A AND 1B, NECK, RIGHT, EXCISION: 1 OF 6 LYMPH NODES INVOLVED BY METASTATIC CARCINOMA (1/6).
- 12) LYMPH NODES, LEVEL 1B, NECK, LEFT, EXCISION: 4 LYMPH NODES, NEGATIVE FOR MALIGNANCY.
- 13) HEMIMANDIBLE AND FLOOR OF MOUTH, RIGHT, COMPOSITE RESECTION: INFILTRATING MODERATELY DIFFERENTIATED KERATINIZING SQUAMOUS CELL CARCINOMA, 4.3 CM IN GREATEST DIMENSION, INVADING INTO UNDERLYING BONE; ALL SURGICAL RESECTION MARGINS, NEGATIVE FOR MALIGNANCY (SEE COMMENT).
- 14) SOFT TISSUE, ADDITIONAL TONGUE, LEFT, EXCISION: SALIVARY GLAND,

[page 2 of 5]
NEGATIVE FOR MALIGNANCY.

COMMENT: These findings correspond to AJCC stage IVA (pT4a, pN1, pMx).

**Electronically Signed Out by [REDACTED]

[REDACTED]

CLINICAL DATA

Clinical Features: Unspecified

Operator: Unspecified

Operation: Unspecified

Operative Findings: Unspecified

Operative Diagnosis: Unspecified

Tissue Submitted: 1) right floor of mouth

GROSS DESCRIPTION:

1) SOURCE: Right Floor of Mouth

Received fresh for frozen section diagnosis are multiple fragments of soft tissue and mucosa measuring 1.2 x 0.8 x 0.4 cm. The tissue is totally submitted.

Summary of sections: 1AFSC, M/1.

2) SOURCE: Level 1 L.N. Adjacent to Facial Artery

Received fresh for frozen section diagnosis is a 0.7 x 0.5 x 0.5 cm fleshy, beige, soft tissue nodule that is totally submitted for frozen section diagnosis.

Summary of sections: 2AFSC, 1/1.

3) SOURCE: Right Distal Lingual Nerve

Received fresh for frozen section diagnosis is a 0.5 x 0.3 x 0.2 cm piece of soft tissue that is inked red and totally submitted.

Summary of sections: 3AFSC, 1/1.

4) SOURCE: Right Tongue Deep Bx

Received fresh for frozen section diagnosis is a piece of tissue, measuring 0.5 x 0.3 x 0.2 cm that is totally submitted.

Summary of sections: 4AFSC, 1/1.

5) SOURCE: Right Posterior Medial Mandibular Margin

Received fresh for frozen section diagnosis is a piece of tissue composed of mucosa and underlying submucosal tissue, measuring 1.1 x 1.0 x 0.3 cm. The resection margin is inked red and the tissue is serially sectioned and totally submitted.

Summary of sections: 5AFSC, 3/1.

[REDACTED]

[page 3 of 5]
6) SOURCE: Right Posterior Alveolar Margin

Received fresh for frozen section diagnosis is a piece of tissue composed of mucosa and underlying soft tissue, measuring 2.3 x 0.9 x 0.4 cm. The resection margin is inked red. The specimen is serially sectioned and totally submitted.

Summary of sections: 6AFSC, 4/1.

7) SOURCE: Right Neck Levels 2-3

Received is a piece of fatty tissue containing multiple nodules and measuring 9.5 x 3.8 x 0.9 cm. A lymph node, measuring 2.3 x 1.7 x 0.6 cm is identified. A smaller lymph node is also identified. The rest of the tissue is fibrofatty with some slippery, nodular, vague structures. A representative section through each of the vague nodular structures is obtained.

Summary of sections: 7A, large lymph node, bisected, smaller lymph node inked black, 3/1; 7B, representative sections through nodular vague structures, 4/1.

8) SOURCE: Right Neck Level 4

Received is a piece of fatty tissue, measuring 3.5 x 2.4 x 1.1 cm. The tissue is dissected for lymph nodes and candidate lymph nodes are submitted.

Summary of sections: 8A, 5/1.

9) SOURCE: Right Neck Level 2B

Received is a 4.3 x 2.9 x 0.7 cm piece of fibrofatty tissue containing lymph nodes, which are dissected and submitted.

Summary of sections: 9A, 4/1.

10) SOURCE: Right Neck Anterior 2-3

Received is a 9.1 x 4.3 x 1.0 cm piece of fibrofatty tissue containing lymph nodes, which are dissected and submitted.

Summary of sections: 10A-B, m/1 each.

11) SOURCE: Right Neck Level 1A-B

Received is a 9.2 x 5.7 x 1.6 cm piece of tissue composed of fatty tissue with salivary gland and adjacent fibrofatty tissue with attached skeletal muscle. The salivary gland measures 3.5 x 3.2 x 1.1 cm. Cut sections reveal dull, beige surfaces with nodularities. There are no lesions identified. The skeletal muscle section measures 3.2 x 3.4 x 0.7 cm and is unremarkable. Multiple lymph nodes are identified, the largest measuring 2.6 x 1.9 x 0.7 cm. The second largest lymph node shows a hemorrhagic center. Sections are submitted as follows:

Summary of sections: 11A, section through salivary gland and skeletal muscle, 2/1; 11B, largest lymph node, bisected, 2/1; 11C, hemorrhagic lymph node, bisected, 1/1; 11D, candidate lymph node, 1/1; 11E, candidate lymph node, 3/1.

[page 4 of 5]
12) SOURCE: Left Level 1B

Received is a piece of fatty tissue containing salivary gland and lymph nodes. The specimen measures 6.7 x 4.8 x 1.3 cm. The salivary gland measures 4.2 x 3.4 x 1.3 cm. Cut surfaces show nodular, dull, yellow, and brown surfaces with no grossly identified lesions. The attached soft tissue is dissected for lymph nodes. The largest lymph node measures 1.6 x 1.0 x 0.4 cm.

Summary of sections: 12A, sections through salivary gland, 1/1; 12B, largest lymph node, which is hemorrhagic, bisected, 1/1; 12C, candidate lymph nodes, 3/1.

13) SOURCE: Composite Resection Anterior

Received is the right hemimandible with associated medially located soft tissue containing tumor. The mandible measures 13.0 cm from anterior midline until the posterior resection margin, 3.0 cm in height from the base of the mandible towards the insertion of the teeth and 1.3 cm in maximal thickness. The specimen shows seven teeth starting from the middling located incisor and going backwards reaching the molar. The anterior resection margin including the bony mandible as well as the soft tissue is inked yellow. The lateral surface of the mandible is inked orange. The posterior resection margin is inked black and that includes the mandibular resection margin and the soft tissue resection margin. The medial resection margin is inked blue and the deep resection margin including soft tissue and mandible is inked green. A firm, tan, ulcerated lesion with raised edges is identified arising from the oral mucosa measuring 4.3 x 2.5 x 2.2 cm. The lesion grossly invades into the underlying bone. The lesion is located 0.1 cm from the closest deep resection margin, 1.3 cm from the closest soft tissue anterior resection margin and 0.6 cm away from the closest lateral mandibular cortex. It is 1.6 cm away from the posterior resection margin and 0.3 cm away from the closest medial resection margin. The patient had dental implants and there are rims of metal underlying the implant caps in the teeth. Representative sections are submitted as follows following decalcification.

Summary of sections: 13A, closest deep margin, 2/1; 13B, closest posterior margin, 2/1; 13C, closest medial margin, 1/1; 13D, soft tissue anterior margin en face, 1/1; 13E, tumor involving medial cortex of the mandible, 1/1; 13F-13G, medial anterior resection margin of the mandible, 1/1 each; 13H, tumor invading through bone, 1/1 each; 13I, posterior resection margin of the mandible.

14) SOURCE: Additional Left Tongue

Received is a piece of skeletal muscle and attached soft tissue, measuring 1.1 x 0.8 x 0.3 cm. The tissue is bisected and totally submitted.

Summary of sections: 14A, 2/1.

[page 5 of 5]
SURGICAL PATHOLOGY INTRAOPERATIVE CONSULTATION

1) SOURCE: Right Floor of Mouth

FROZEN SECTION DIAGNOSIS: INVASIVE SQUAMOUS CELL CARCINOMA. [REDACTED]

2) SOURCE: Level 1 lymphnode Adjacent to Facial Artery

FROZEN SECTION DIAGNOSIS: BENIGN. [REDACTED]

3) SOURCE: Right Distal Lingual Nerve

FROZEN SECTION DIAGNOSIS: BENIGN. [REDACTED]

4) SOURCE: Right Tongue Deep Bx

FROZEN SECTION DIAGNOSIS: BENIGN. [REDACTED]

5) SOURCE: Right Posterior Medial Mandibular Margin

FROZEN SECTION DIAGNOSIS: BENIGN. [REDACTED]

6) SOURCE: Right Posterior Alveolar Margin

FROZEN SECTION DIAGNOSIS: BENIGN. [REDACTED]

Electronically signed by: [REDACTED]

The following special studies were performed on this case and the interpretation is incorporated in the diagnostic report above:
5xDECALCIFICATION OF BLOCK

In some tests, analyte specific reagents (ASRs) are used. In the case of an ASR, this test was developed and its performance characteristics determined by this laboratory. It has not been cleared or approved by the US Food and Drug Administration. The FDA has determined that such clearance or approval is not necessary. This test is used for clinical purposes. It should not be regarded as investigational or for research. This laboratory is certified under the Clinical Laboratory Improvement Amendments of [REDACTED] (CLIA [REDACTED]) as qualified to perform high complexity clinical laboratory testing.
SNOMED: T-11001,T-11001,M-80703,

[REDACTED]

Source: NCI Genomic Data Commons file b60bce70-7684-4107-aa88-613f9219f7f5 (TCGA-CR-7368.B05D6335-5490-4CA7-ADAB-2A15B6E91C8D.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).